Surgical pathology report (de-identified scan), TCGA case TCGA-J1-A4AH, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J1-A4AH-01A (Primary Tumor).

[page 1 of 6]
Name
Encounter Number

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Results

Final

Source of Specimen

- A. 4R#1-
- B. 4R#2-
- C. 4R#3-
- D. 4L NODES - FS-
- E. STATION 7 NODES - FS-
- F. STATION #9-
- G. STATION 11 NODE #1-
- H. STATION 11 NODE #2-
- I. STATION 7 #2-
- J. STATION 5 #2-
- K. STATION 5 #3-
- L. STATION 10-
- M. STATION 5 #1-
- N. PERI-AORTIC NODE-
- O. BRONCHIAL MARGIN FS-
- P. LEFT LUNG NFS-

1CD-0-3

Carcinoma, squamous cell NOS 8070/3

Site: lung, lower lobe C34.3

hw
9/24/12

FINAL DIAGNOSIS:

- A. 4R#1-
NO CARCINOMA SEEN IN THREE LYMPH NODES (0/3).
- B. 4R#2-
NO CARCINOMA SEEN IN ONE LYMPH NODE (0/1).
- C. 4R#3-
NO CARCINOMA SEEN IN TWO LYMPH NODES (0/2).
- D. 4L NODES - FS-
NO CARCINOMA SEEN IN ONE LYMPH NODE (0/1).
- E. STATION 7 NODES - FS-
NO CARCINOMA SEEN IN FIVE LYMPH NODES (0/5).

Prep:

[page 2 of 6]
F. STATION #9-
NO CARCINOMA SEEN IN ONE LYMPH NODE (0/1).
G. STATION 11 NODE #1-
NO CARCINOMA SEEN IN ONE LYMPH NODE (0/1).
H. STATION 11 NODE #2-
NO CARCINOMA SEEN IN ONE LYMPH NODE (0/1).
I. STATION 7 #2-
NO CARCINOMA SEEN IN ONE LYMPH NODE (0/1).
J. STATION 5 #2-
NO CARCINOMA SEEN IN ONE LYMPH NODE (0/1).
K. STATION 5 #3-
NO CARCINOMA SEEN IN ONE LYMPH NODE (0/1).
L. STATION 10-
NO CARCINOMA SEEN IN TWO LYMPH NODES (0/2).
M. STATION 5 #1-
NO CARCINOMA SEEN IN ONE LYMPH NODE (0/1).
N. PERI-AORTIC NODE-
NO CARCINOMA SEEN IN ONE LYMPH NODE (0/1).
O. BRONCHIAL MARGIN FS-
SEE PART P FOR DIAGNOSIS.
P. LEFT LUNG NFS-
INVASIVE CARCINOMA.

HISTOLOGIC TYPE: SQUAMOUS.

HISTOLOGIC GRADE: 2-3/3.

TUMOR FOCALITY: UNIFOVAL.

TUMOR SIZE: 6 CM.

TUMOR SITE: LEFT LOWER LOBE.

TREATMENT EFFECT: NOT SEEN.

VISCERAL PLEURA INVASION: NOT PRESENT.

ATELECTASIS/OBSTRUCTIVE PNEUMONITIS EXTENDING TO HILUM: NOT SEEN.

LYMPHATIC (SMALL VESSEL) INVASION: RARE SUSPICIOUS FOCI SEEN.

LARGE VESSEL INVASION: NOT SEEN.

0 OF 7 PERIBRONCHIAL NODES ARE POSITIVE FOR METASTATIC TUMOR.

LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER INVOLVED : 0
NUMBER EXAMINED: 22

Prepared for

[page 3 of 6]
TNM STAGE: pT2b, pN0, pMX.

SPECIMEN TYPE: LEFT PNEUMONECTOMY.

SPECIMEN SIZE: 21 X 13 X 7 CM.

NO TUMOR SEEN AT RESECTION MARGINS.

Signed Others

Case Clinical Information
LEFT LOWER LUNG CA

Gross Description

- A. Received in formalin labeled with the patient's name and "4R#1" are three focally anthracotic yellow tissues measuring up to 3 mm each. Totally submitted in A1.
- B. Received in formalin labeled with the patient's name and "4R#2" are four fatty tissues measuring up to 3 mm in greatest dimension each. Entirely submitted in B1.
- C. Received in formalin labeled with the patient's name and "4R#3" are two focally anthracotic and yellow/tan tissues measuring up to 5 mm in greatest dimension each. Submitted totally in C1.
- D. Received in formalin labeled with the patient's name and "4L nodes-FS" is a focally anthracotic yellow/tan tissue measuring 5 mm in greatest dimension. Submitted totally in D1.
- E. Received in formalin labeled with the patient's name and "station 7 nodes-FS" are 10 fragments of focally anthracotic yellow/tan tissue measuring 1 x 1 x 1 cm in compact aggregate. All material is submitted wrapped in E1.
- F. Received in formalin labeled with the patient's name and "station #9" is focally anthracotic yellow/tan tissue measuring 7 mm in greater dimension. Submitted totally in F1.
- G. Received in formalin labeled with the patient's name and "station 11, node #1" is an anthracotic, moderately firm tissue measuring 8 x 7 x 6 mm. Submitted totally in G1.
- H. Received in formalin labeled with the patient's name and "station 11, node #2" is a focally anthracotic yellow/tan tissue measuring 6 mm in greatest dimension. Submitted totally in H1.

Prepared for

[page 4 of 6]
I. Received in formalin labeled with the patient's name and "station 7, #2" is focally anthracotic yellow/tan tissue measuring 12 x 6 x 5 mm. Submitted totally, bisected in I1.

J. Received in formalin labeled with the patient's name and "station 5, #2" is a focally anthracotic yellow/tan tissue measuring 4 mm in greatest dimension. Submitted totally in J1.

K. Received in formalin labeled with the patient's name and "station 5, #3" is a focally anthracotic yellow/tan tissue measuring 12 x 6 x 4 mm. Submitted totally in K1.

L. Received in formalin labeled with the patient's name and "station 10" is a yellow/tan tissue measuring 9 x 5 x 3 mm. Submitted totally in L1.

M. Received in formalin labeled with the patient's name and "station 5, lymph node 1" is a focally anthracotic yellow/tan tissue measuring 1.5 x 0.8 x 0.6 cm in greatest dimensions. Submitted totally in M1.

N. Received in formalin labeled with the patient's name and "peri-aortic" are two focally anthracotic yellow/tan tissues. Each measures up to 3 mm in greatest dimensions. Submitted totally in N1.

O. Received in formalin labeled with the patient's name and "bronchial margin-FS" is a ring of cartilage and soft tissue measuring 2 x 2 x 0.3 cm thick. Submitted totally in O1.

P. Received in formalin labeled with the patient's name and "left lung" is a pneumonectomy specimen weighing 425 grams and measuring 21 x 13 x 7 cm in greatest dimensions. The hilar aspect is inked black at this time. The pleural aspect has been previously dissected over an area of tumor measuring 6 x 6 x 5 cm in greatest dimensions. The tumor extends to within 5 mm of the current inked bronchial margin (not true margin, which is sampled by frozen section). The section code is as follows:
P1-P6=extensive sampling of hilar margin perpendicular to inked surface (parallel to airways and vascular structures) to include scattered areas of anthracosis consistent with lymph nodes;
P7=indurated lung distal to tumor; P8-P11=extensive sampling of tumor which appears friable, white and focally necrotic; and
P12=representative section of grossly uninvolved lung.

Procedure

A. AA ROUTINE H&E X1 BLOCK

H&E X1

B. AA ROUTINE H&E X1 BLOCK

[page 5 of 6]
H&E X1
C. AA ROUTINE H&E X1 BLOCK
H&E X1
D. AA ROUTINE H&E X1 BLOCK
H&E X1
E. AA ROUTINE H&E X1 BLOCK
H&E X1
F. AA ROUTINE H&E X1 BLOCK
H&E X1
G. AA ROUTINE H&E X1 BLOCK
H&E X1
H. AA ROUTINE H&E X1 BLOCK
H&E X1
I. AA ROUTINE H&E X1 BLOCK
H&E X1
J. AA ROUTINE H&E X1 BLOCK
H&E X1
K. AA ROUTINE H&E X1 BLOCK
H&E X1 A RECUTS
L. AA ROUTINE H&E X1 BLOCK
H&E X1
M. AA ROUTINE H&E X1 BLOCK
H&E X1
N. AA ROUTINE H&E X1 BLOCK
H&E X1
O. AA ROUTINE H&E X1 BLOCK
H&E X1
P. AA ROUTINE H&E X1 BLOCK.1
H&E X1
P. AA ROUTINE H&E X1 BLOCK.2
H&E X1
P. AA ROUTINE H&E X1 BLOCK.3
H&E X1
P. AA ROUTINE H&E X1 BLOCK.4
H&E X1
P. AA ROUTINE H&E X1 BLOCK.5
H&E X1
P. AA ROUTINE H&E X1 BLOCK.6
H&E X1
P. AA ROUTINE H&E X1 BLOCK.7
H&E X1
P. AA ROUTINE H&E X1 BLOCK.8
H&E X1
P. AA ROUTINE H&E X1 BLOCK.9
H&E X1
P. AA ROUTINE H&E X1 BLOCK.10
H&E X1
P. AA ROUTINE H&E X1 BLOCK.11

Prepa

[page 6 of 6]
H&E X1
P. AA ROUTINE H&E X1 BLOCK.12
H&E X1

Prepared for

Source: NCI Genomic Data Commons file 568a3dab-2df1-4ed1-b51e-8c01c49d66b1 (TCGA-J1-A4AH.27031EAD-6E93-4973-869E-EFE13B7F899A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).